Gene-level copy-number profile of tumor specimen ALCH-B3CC-TTP1-A from ALCHEMIST case ALCH-B3CC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.9 years (24,805 days).
Specimen ALCH-B3CC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eda764ce-4ef2-4460-9321-6096d9cd76f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3CC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/4e8088bb-4857-4b76-bf7a-20a23347c9d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 1,603; copy number 2: 56,498; copy number 3: 228; copy number 4: 30; copy number 5: 4; copy number 8: 1; copy number 9: 1; copy number 12: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–921,016, 4 genes: AL645608.6, AL645608.2, AL645608.4, LINC02593.
- chr1:998,962–1,000,172, 1 gene: HES4.
- chr1:109,249,539–109,283,186, 2 genes: CELSR2, PSRC1.
- chr4:128,069,014–128,069,612, 1 gene (within-gene range 0–2): AC099340.1.
- chr5:132,060,655–132,080,133, 3 genes: IL3, CSF2, AC034216.1.
- chr6:44,158,811–44,184,401, 1 gene: CAPN11.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–2): FLNC, FLNC-AS1.
- chr8:12,341,426–12,388,296, 5 genes: DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2.
- chr14:100,323,339–100,330,421, 1 gene: SLC25A47.
- chr16:46,884,362–46,931,289, 1 gene: GPT2.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–2): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr17:61,361,668–61,413,280, 5 genes (within-gene range 0–2): AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875.
- chr19:41,397,808–41,428,730, 4 genes (within-gene range 0–2): BCKDHA, AC011462.3, AC011462.2, B3GNT8.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.
- chr22:46,576,012–46,679,790, 1 gene: GRAMD4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–1,984,522, 1 gene, copy number 8 (within-gene range 3–8): MRPL23.
- chr16:1,833,986–1,884,294, 3 genes, copy number 5 (within-gene range 3–5): MEIOB, AL031722.1, LINC00254.
- chr21:43,414,483–43,427,131, 1 gene, copy number 12: SIK1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 5–16: LINC00313, AP001048.1.
- chr22:18,650,023–18,653,617, 1 gene, copy number 9: PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 1,603. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
